Somatic mutation profile of tumor specimen TCGA-04-1349-01A (aliquot TCGA-04-1349-01A-01W-0494-09) from TCGA case TCGA-04-1349, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.0 years (25,213 days).
Specimen TCGA-04-1349-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57a594a4-7429-468f-83fb-411bd117ab6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1349-11A (Solid Tissue Normal), aliquot TCGA-04-1349-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b95134e-7daa-4ba0-88d8-719145443e17

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 52/62 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKS1A | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 48/178 reads (27%) | catalogued as rs770431088, COSV64462173; called by muse, mutect2, varscan2
- BACH2 | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 79/113 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100001244; called by muse, mutect2, varscan2
- CAMK2D | c.1162T>G p.L388V | Missense Mutation (SNP) | VAF 278/685 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56434359; called by muse, mutect2, varscan2
- FAM117B | c.1588A>T p.K530* | Nonsense Mutation (SNP) | VAF 243/329 reads (74%) | catalogued as COSV57419867, COSV57420354; called by muse, mutect2, varscan2
- FAR1 | c.1271A>T p.D424V | Missense Mutation (SNP) | VAF 110/146 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61385487; called by muse, mutect2, varscan2
- FARSA | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs749068256, COSV58905310; called by muse, mutect2, varscan2
- FCGR1A | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV100977318; called by muse, mutect2, varscan2
- GPR158 | c.2308T>C p.S770P | Missense Mutation (SNP) | VAF 114/638 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66275263; called by muse, mutect2, varscan2
- GTF2H4 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV99462338; called by muse, mutect2
- HMCN1 | c.5641C>T p.R1881* | Nonsense Mutation (SNP) | VAF 314/602 reads (52%) | catalogued as rs762269912, COSV54951014; called by muse, varscan2
- HSPG2 | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.1); catalogued as COSV101013018; called by muse, mutect2, varscan2
- KRT79 | c.915C>A p.N305K | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57940828; called by muse, mutect2, varscan2
- LRBA | c.6643T>A p.W2215R | Missense Mutation (SNP) | VAF 102/623 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63958970; called by muse, mutect2, varscan2
- LRIG3 | c.1654C>G p.L552V | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.098); catalogued as COSV57866505; called by muse, mutect2, varscan2
- MCM9 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 183/253 reads (72%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs779438644, COSV60164616; called by muse, mutect2, varscan2
- MFSD9 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs767201966, COSV51494591; called by muse, mutect2, varscan2
- NCAM2 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53086949, COSV53105266; called by muse, mutect2, varscan2
- NNT | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV52926868; called by muse, mutect2, varscan2
- NUP188 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs375622238; called by muse, mutect2, varscan2
- PADI2 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); catalogued as rs764725762, COSV64946095; called by muse, mutect2
- PCDH15 | c.3773C>A p.T1258N | Missense Mutation (SNP) | VAF 184/489 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1288310417, COSV100223745, COSV57346062; called by muse, mutect2, varscan2
- PDGFRA | c.1624C>T p.L542F | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1060501522, COSV99957874; ClinVar: uncertain significance; called by muse, mutect2
- PPP2CA | c.362G>C p.R121T | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51538534; called by muse, mutect2, varscan2
- PRICKLE1 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs553919252, COSV61544461; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs768493495, COSV54582056; called by muse, mutect2, varscan2
- RB1CC1 | c.947A>G p.D316G | Missense Mutation (SNP) | VAF 72/492 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV50256305; called by muse, mutect2, varscan2
- SOBP | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.236); catalogued as COSV58000099; called by muse, mutect2, varscan2
- TTC3 | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 144/339 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61292998; called by muse, mutect2, varscan2
- VWA3B | c.2746A>G p.N916D | Missense Mutation (SNP) | VAF 204/487 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV68244470; called by muse, mutect2, varscan2
- KIF21B | c.4505dup p.H1503Afs*22 (on ENST00000422435 / NM_001252100.2; = p.H1490Afs*22 on NM_017596.4) | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- ACAN | c.2259G>T p.P753= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV61360803; called by muse, varscan2
- AL035460.1 | c.240C>T p.L80= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV100730200; called by muse, mutect2, varscan2
- CBX7 | c.615C>A p.A205= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as COSV53358835, COSV53359452; called by muse, mutect2, varscan2
- DAO | c.249C>T p.N83= | Silent (SNP) | VAF 156/811 reads (19%) | catalogued as rs149638037, COSV57323067; called by muse, mutect2, varscan2
- PGAP1 | c.336A>G p.A112= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as rs930613787, COSV61327565; called by muse, mutect2, varscan2
- PLEK2 | c.363C>T p.F121= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53605947; called by muse, mutect2, varscan2
- PLTP | c.288C>A p.S96= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- SHISAL1 | c.153G>A p.S51= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs565301340, COSV66988284; called by muse, mutect2, varscan2
- TTC9C | c.144G>T p.P48= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV53666203; called by muse, mutect2, varscan2
- TYRO3 | c.2526C>T p.G842= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99778181; called by muse, varscan2
- AC024940.1 | n.2355G>T | RNA (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2
- CADM2 | c.62-75543A>G | Intron (SNP) | VAF 31/163 reads (19%) | catalogued as COSV67387292; called by muse, mutect2, varscan2
- SGCZ | c.40-298557T>A | Intron (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100763107; called by muse, mutect2, varscan2
